Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6WE, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6WE-01A (Primary Tumor).

Neuropathology

Patient:

B-Day:

Patho-No.:

ICD-O-3
Oligodendroglioma, grade II
9450/3 NOS
Site Brain, supratentorial
C71.0
JW 8/12/13

Commentary:

This case was initially diagnosed as anaplastic oligodendroglioma. Upon review, histology and morphology best corresponds to oligodendroglioma WHO grade II.

Diagnosis:

Oligodendroglioma WHO grade II

Untranslated full report
is housed at the BCR.

Criteria	hw 7/16/13	No
For Malignancy History		✓
Qual. Synchronous Primary Noted		✓

Source: NCI Genomic Data Commons file 2c3bb069-28be-4964-aa0c-23ecdbc4c479 (TCGA-S9-A6WE.F17B7D4A-F22C-472A-A84F-51CABBA8BE44.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).